Somatic mutation profile of tumor specimen MP2PRT-PAPVGP-TMP1-A (aliquot MP2PRT-PAPVGP-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PAPVGP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (933 days).
Specimen MP2PRT-PAPVGP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5baaa147-7141-471e-85a3-c6ae4d62f3f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPVGP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPVGP-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40ffd91d-fa2b-4cec-b1d0-05ef6681d63f

The open-access MAF lists 18 somatic variants for this specimen: 11 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 6, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GABRE | c.847C>G p.Q283E | Missense Mutation (SNP) | VAF 39/701 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as COSV64821449; called by muse, mutect2
- HHIPL1 | c.1880G>A p.R627Q | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs905505445; called by muse, mutect2
- KMT2C | c.3599C>G p.S1200* | Nonsense Mutation (SNP) | VAF 18/447 reads (4%) | catalogued as COSV51433846; called by muse, mutect2
- ANKRD26 | c.3927G>A p.M1309I | Missense Mutation (SNP) | VAF 15/336 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2
- FSIP2 | c.10216G>C p.D3406H | Missense Mutation (SNP) | VAF 112/285 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- FSIP2 | c.19396C>A p.P6466T | Missense Mutation (SNP) | VAF 74/235 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- NIP7 | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 24/390 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.832); called by muse, mutect2
- PTH2R | c.241A>T p.I81L | Missense Mutation (SNP) | VAF 41/370 reads (11%) | SIFT tolerated (0.93); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SELPLG | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 45/939 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.647); called by muse, mutect2
- TGFBR3L | c.59G>A p.G20D | Missense Mutation (SNP) | VAF 284/733 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- ZNF729 | c.2456C>A p.T819N | Missense Mutation (SNP) | VAF 131/466 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- AC068580.4 | c.1440C>T p.N480= | Silent (SNP) | VAF 22/578 reads (4%) | catalogued as COSV100415200; called by muse, mutect2
- CDKN2A | c.470G>A p.*157= | Silent (SNP) | VAF 29/523 reads (6%) | catalogued as COSV58721717; called by muse, mutect2
- TMEM94 | c.2520C>T p.L840= | Silent (SNP) | VAF 42/593 reads (7%) | catalogued as rs776598558; called by muse, mutect2
- TNFSF9 | c.591C>T p.F197= | Silent (SNP) | VAF 54/818 reads (7%) | catalogued as rs375425240, COSV55538150, COSV55538733; called by muse, mutect2
- UBIAD1 | c.669C>T p.L223= | Silent (SNP) | VAF 39/670 reads (6%) | catalogued as rs1020032732; called by muse, mutect2
- WWTR1 | c.270G>A p.S90= | Silent (SNP) | VAF 43/798 reads (5%) | catalogued as rs758204408, COSV62291321; called by muse, mutect2
- PPP1R9A | c.2757+5253A>G | Intron (SNP) | VAF 153/345 reads (44%) | called by muse, mutect2, varscan2
